CPTAC case C3N-01338 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ef730c6c-0231-4c58-b633-c327451cda42

Demographics
Sex at birth: male; Race: white; Year of birth: 1967; Vital status: Dead; Days to death: 585 days (1.6 years); Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 50.2 years (18,322 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 585 days (1.6 years); Progression or recurrence: yes; Days to recurrence: 492 days (1.3 years); Days to last follow up: 574 days (1.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 3 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 13; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 284 days; Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 574 days (1.6 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 492 days (1.3 years); Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 574 days (1.6 years); Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 75 kg; Height: 175 cm; BMI: 24.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01338-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -35 days; Initial weight: 123 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01338-21: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-01338-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -35 days; Initial weight: 133 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01338-22: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-01338-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -35 days; Initial weight: 139 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01338-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -36 days; Method of sample procurement: Blood Draw.
